Somatic mutation profile of tumor specimen TARGET-10-PAPHCA-09A (aliquot TARGET-10-PAPHCA-09A-01D) from TARGET case TARGET-10-PAPHCA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (892 days).
Specimen TARGET-10-PAPHCA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fad8160-fa6e-48e9-b775-da08c265b56f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHCA-14A (Bone Marrow Normal), aliquot TARGET-10-PAPHCA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ef45ad9-8ecc-425c-b721-eab8baa244df

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Nonsense Mutation 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- UNC80 | c.5671C>T p.R1891* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as rs1262654975, COSV55886621; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNTN3 | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs200380587; called by muse, mutect2, varscan2
- DCAF8L1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs757727199, COSV71595234; called by muse, mutect2, varscan2
- DNAH10 | c.5891C>T p.T1964M (on ENST00000409039; = p.T1903M on NM_207437.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs377607369; called by muse, mutect2
- LRCH3 | c.1042C>G p.L348V | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1487689615; called by muse, mutect2
- MYPN | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100590432; called by muse, mutect2, varscan2
- B3GALT4 | c.736G>C p.V246L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IL17RA | c.1881_1896del p.G628Wfs*3 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- SHC4 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- IQGAP1 | c.408T>A p.T136= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- SHC2 | c.765C>T p.G255= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs182383668; called by muse, mutect2, varscan2
- TMCC1 | c.723C>T p.I241= | Silent (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- MID2 | c.*19A>G | 3'UTR (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
